Somatic mutation profile of tumor specimen TARGET-20-PATAVF-09A (aliquot TARGET-20-PATAVF-09A-01D) from TARGET case TARGET-20-PATAVF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.5 years (7,120 days).
Specimen TARGET-20-PATAVF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad3309c8-9bea-4c27-abee-80cca2cb9cdb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATAVF-14A (Bone Marrow Normal), aliquot TARGET-20-PATAVF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc39bb2c-1780-4e40-9844-01dd0ca8b366

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Splice Site 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1096-1G>T p.X366_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as rs397517076, CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NALCN | c.1519G>A p.G507R | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTLL12 | c.1176C>T p.N392= | Silent (SNP) | VAF 39/63 reads (62%) | catalogued as rs777234765; called by muse, mutect2, varscan2
